Somatic mutation profile of tumor specimen TCGA-D1-A102-01A (aliquot TCGA-D1-A102-01A-11D-A10M-09) from TCGA case TCGA-D1-A102, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 49.3 years (17,991 days).
Specimen TCGA-D1-A102-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7838e7a0-0c3f-4fd1-91e0-eca29fcc13ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A102-10A (Blood Derived Normal), aliquot TCGA-D1-A102-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b5dcb8f-5549-4aa1-aec6-26f5e58a2b2b

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, In Frame Del 4, Frame Shift Del 1, Nonsense Mutation 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs140853839, CM067636; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 29/70 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as rs121913275, COSV55874040, COSV55875881, COSV55956933; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADRM1 | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV53362896; called by muse, varscan2
- ASTL | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759833663, COSV60904606; called by muse, mutect2, varscan2
- BSN | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as rs372598293, COSV56528908; called by muse, varscan2
- BTK | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs1555980039, COSV58121042; called by muse, varscan2
- CHMP4C | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV51927560; called by muse, mutect2, varscan2
- CLEC3A | c.581G>T p.S194I (on ENST00000651443; = p.S185I on NM_005752.6) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV55222065; called by muse, mutect2, varscan2
- COL4A5 | c.2480C>A p.P827Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV60364230; called by muse, mutect2, varscan2
- CROCC | c.802C>G p.R268G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs144174614, COSV100978165, COSV65012941; called by muse, mutect2, varscan2
- DNAH9 | c.7094G>A p.C2365Y | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.27); catalogued as COSV52356600; called by muse, mutect2, varscan2
- EPHA5 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs910705978, COSV56652007, COSV56655869; called by muse, mutect2, varscan2
- EYA4 | c.1930T>A p.Y644N (on ENST00000531901 / NM_001301013.1; = p.Y638N on NM_004100.5) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62054523; called by muse, mutect2
- GABRA3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 73/131 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV64795195; called by muse, mutect2, varscan2
- KIAA0753 | c.-1_2del | Translation Start Site (DEL) | VAF 33/91 reads (36%) | catalogued as rs1333855921; called by mutect2, pindel, varscan2
- MLLT1 | c.345C>G p.N115K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53131291; called by muse, mutect2, varscan2
- MMP2 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV54602580; called by muse, mutect2
- MR1 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs956380752, COSV51581208; called by muse, mutect2, varscan2
- MYO9A | c.543T>G p.S181R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61853001; called by muse, mutect2, varscan2
- OR10G9 | c.667T>A p.S223T | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV66686397; called by muse, mutect2
- OR13C5 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV66164778; called by muse, mutect2, varscan2
- OR9I1 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV56926388; called by muse, mutect2, varscan2
- PCM1 | c.5017_5019del p.L1673del | In Frame Del (DEL) | VAF 25/123 reads (20%) | catalogued as rs746038417; called by pindel, varscan2
- PHF6 | c.567A>T p.E189D (on ENST00000332070 / NM_032458.3; = p.E190D on NM_032335.3) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59703627; called by muse, mutect2, varscan2
- PPP2R1A | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1489963266, COSV59045663; called by muse, mutect2, varscan2
- PSMD11 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs761320521, COSV55577373; called by muse, mutect2, varscan2
- RAB41 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV52104445; called by muse, mutect2, varscan2
- RBFOX1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.069); catalogued as rs527782263, COSV60944925; called by muse, mutect2, varscan2
- SCO1 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147039721; called by muse, mutect2
- SLC22A6 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs764704425, COSV64560393; called by muse, mutect2, varscan2
- TNIP1 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as rs778977275, COSV59307840; called by muse, mutect2, varscan2
- TTC21A | c.3124G>C p.G1042R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56188802; called by muse, mutect2, varscan2
- UBR5 | c.3895_3896del p.R1299Gfs*4 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | catalogued as COSV55290969; called by mutect2, pindel, varscan2
- ZP2 | c.1130T>C p.F377S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54811902, COSV54814723; called by muse, mutect2, varscan2
- C8orf74 | c.225_227del p.L76del | In Frame Del (DEL) | VAF 36/139 reads (26%) | called by pindel, varscan2
- SASH1 | c.633_635del p.E212del | In Frame Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- SGK1 | c.1095_1097del p.N365del | In Frame Del (DEL) | VAF 55/158 reads (35%) | called by pindel, varscan2
- ANGPTL8 | c.438C>T p.Y146= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV52949122; called by muse, mutect2, varscan2
- DAO | c.786C>A p.G262= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV57323047; called by muse, mutect2, varscan2
- FOXN3 | c.447G>A p.P149= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs183597395, COSV54307289; called by muse, mutect2, varscan2
- LHX9 | c.444C>T p.R148= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV61329580; called by muse, mutect2, varscan2
- MEIS2 | c.153C>T p.Y51= (on ENST00000561208 / NM_170675.5; = p.Y38= on NM_002399.3) | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs140890748; called by muse, mutect2, varscan2
- SIGLEC1 | c.2508G>A p.L836= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV52466077; called by muse, mutect2, varscan2
- TEAD4 | c.969C>T p.P323= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs376977078, COSV100622003; called by muse, mutect2, varscan2
- TNKS | c.3420C>T p.G1140= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV60060597; called by muse, mutect2, varscan2
- TRIL | c.2373G>A p.A791= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1281682973, COSV59867357; called by muse, mutect2
- TTN | c.39666G>A p.T13222= (on ENST00000591111; = p.T5798= on NM_003319.4) | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs369800903, COSV59873893; ClinVar: likely benign / benign / conflicting interpretations of pathogenicity; called by muse, varscan2
- USP24 | c.5667G>A p.G1889= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV53770595; called by muse, mutect2, varscan2
- ZNF536 | c.504G>A p.A168= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs547189963, COSV62826661; called by muse, mutect2, varscan2
- ZNF558 | c.954A>G p.K318= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV56863551; called by muse, mutect2, varscan2
- RHOT1 | c.1739+2867C>T | Intron (SNP) | VAF 26/74 reads (35%) | catalogued as COSV61716525; called by muse, mutect2, varscan2
